Somatic mutation profile of tumor specimen TCGA-XM-A8RB-01A (aliquot TCGA-XM-A8RB-01A-11D-A423-09) from TCGA case TCGA-XM-A8RB, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 68.7 years (25,080 days).
Specimen TCGA-XM-A8RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a935bb07-0fab-4d8a-8a5e-5655f0bb3dee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RB-10A (Blood Derived Normal), aliquot TCGA-XM-A8RB-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4185d52b-e49c-4394-9aed-1cd5c03f05d3

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLTC | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PCNT | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- CCT3 | c.624C>A p.I208= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
